Somatic mutation profile of tumor specimen TCGA-DJ-A3UX-01A (aliquot TCGA-DJ-A3UX-01A-11D-A22D-08) from TCGA case TCGA-DJ-A3UX, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 46.9 years (17,124 days).
Specimen TCGA-DJ-A3UX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98cda60b-3b59-47fd-95fe-6b11d41ef4d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3UX-10A (Blood Derived Normal), aliquot TCGA-DJ-A3UX-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29137258-6c23-41a4-8b27-72735ce53dbb

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- NPM3 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV63382128; called by muse, mutect2, varscan2
- STAB2 | c.4522G>T p.G1508C | Missense Mutation (SNP) | VAF 79/453 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101185857, COSV66337155; called by muse, mutect2, varscan2
